Gene-level copy-number profile of tumor specimen TCGA-YG-AA3P-06A from TCGA case TCGA-YG-AA3P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.4 years (23,515 days).
Specimen TCGA-YG-AA3P-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.1b087e6f-256b-4285-99eb-7216e654c153.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YG-AA3P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67517c05-458c-434c-a47b-7008da148f16

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12,281; copy number 3: 16,477; copy number 4: 19,920; copy number 5: 3,163; copy number 6: 4,170; copy number 7: 2,481; copy number 8: 121; copy number 9: 74; copy number 10: 64; copy number 11: 317; copy number 12: 631; copy number 14: 10; copy number 15: 1; copy number 17: 4; copy number 18: 14; copy number 20: 3; copy number 21: 23; copy number 25: 1; copy number 32: 5; copy number 45: 6; copy number 46: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YG-AA3P-06A-11D-A38F-01): tumor purity 0.97, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,192 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,193,072–67,546,754, 33 genes, copy number 20–45: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P.
- chr8:80,967,810–81,284,777, 9 genes, copy number 9: PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr8:93,134,095–145,066,685, 846 genes, copy number 11–12 (within-gene range 7–12) (broad region; genes not listed).
- chr9:71,589,601–72,257,193, 11 genes, copy number 11 (within-gene range 4–11): RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA.
- chr9:79,850,871–80,034,555, 7 genes, copy number 11: AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507.
- chr11:57,712,582–57,818,431, 1 gene, copy number 11 (within-gene range 5–11): AP001931.2.
- chr11:57,741,779–58,442,758, 36 genes, copy number 11 (within-gene range 5–11): AP001931.1, BTBD18, CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12.
- chr11:66,614,964–66,846,552, 11 genes, copy number 11: RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1.
- chr11:66,856,647–66,860,475, 1 gene, copy number 11: LRFN4.
- chr11:67,490,245–67,653,404, 14 genes, copy number 11: MIR6752, PITPNM1, CDK2AP2, CABP2, AP001184.1, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1.
- chr11:69,985,876–70,207,390, 10 genes, copy number 18: AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr11:70,278,921–70,363,368, 4 genes, copy number 18 (within-gene range 4–18): H2AZP4, AP002336.2, MIR548K, AP002336.1.
- chr11:73,264,505–74,324,705, 36 genes, copy number 10 (within-gene range 2–10): P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1.
- chr11:74,685,224–75,018,893, 15 genes, copy number 11: RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3.
- chr11:75,759,512–75,815,406, 4 genes, copy number 11 (within-gene range 2–11): DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr11:75,835,215–75,837,645, 2 genes, copy number 11: Y_RNA, Y_RNA.
- chr11:76,759,916–78,574,874, 49 genes, copy number 14–46 (within-gene range 2–46): AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1.
- chr12:24,566,964–25,648,579, 28 genes, copy number 10 (within-gene range 7–10): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr20:33,965,162–34,560,345, 26 genes, copy number 9: PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A.
- chr20:42,072,752–43,189,970, 2 genes, copy number 9 (within-gene range 2–16): PTPRT, AL035666.1.
- chr20:45,607,939–45,725,830, 8 genes, copy number 17–21: WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617, SPINT4.
- chr20:46,499,630–46,550,654, 2 genes, copy number 15–25 (within-gene range 5–25): ZNF334, OCSTAMP.
- chr20:52,192,159–52,890,386, 9 genes, copy number 9 (within-gene range 2–9): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1.
- chr20:54,153,446–54,183,129, 2 genes, copy number 9: CYP24A1, AL133335.2.
- chr20:54,475,593–54,859,812, 2 genes, copy number 9: DOK5, RNU4ATAC7P.
- chr20:62,402,236–62,776,996, 24 genes, copy number 9: AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
